Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A60L, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A60L-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

ICD-O-3
Astrocytoma NOS 9400/3
Site ^{CCF} Supratentorial NOS
path ^{C71.0} Brain, temporal
lobe C71.2
JW 4/16/13

Study ID:

Patient Age/Sex / F

SPECIMEN SUBMITTED:

LEFT TEMPORAL TUMOR MASS

Final Diagnosis

Left temporal tumor, excision - Low-grade astrocytoma (WHO grade II).
- See comment.

Diagnosis Comment:

The tissue shows moderate hypercellularity with mild nuclear pleomorphism. Mitotic activity is not seen.
Vascular proliferation and necrosis is absent.

Brain and Spinal Cord Tumor Case Summary:

Specimen type: Temporal tumor excision

Specimen handling: Frozen section evaluation and permanent evaluation.

Site: Temporal lobe

Laterality: Left

Diagnosis: Low-grade astrocytoma

WHO Grade: II

Ancillary test(s) ordered: Immunohistochemistry for Ki-67, p53, IDH1 (R132H); FISH for 1p, 19q, and EGFR; all to be performed on block A3 and to be reported as an addendum.

Procedure: ADDENDUM

Status: Signed Out

Text: Ki-67 labeling index is 5%. No nuclei label with antibodies to p53. The neoplastic cells label with antibodies to IDH1 (R132H).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the
The U.S. Food
and Drug Administration has not approved or cleared this test; however, FDA clearance
or approval is not currently required for clinical use.

Prior Malignancy Hist.ory		
Dual/Sync.hronous Primary/Noted		

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Procedure: FISH for 1p/19q

Status: Signed Out

Text: ***** 1p/19q FISH RESULTS *****

RESULTS

Chromosome 1p: Intact, eusomic

Chromosome 19q: Intact, eusomic

Quantitative FISH results:

1p36: 2.3

1q25: 2.3

1p36/1q25 ratio: 1.0

19q13: 2.6

19p13: 2.5

19q13/19p13 ratio: 1.0

SPECIMEN SUBMITTED: Paraffin block A3

INTERPRETATION

1p intact: A majority of nuclei showed similar numbers of 1p36 and 1q25 signals. There is no evidence of allelic loss on the short arm of chromosome 1 (1p).

19q intact: A majority of nuclei showed similar numbers of 19q13 and 19p13 signals. There is no evidence of allelic loss of 19q.

Allelic loss at one locus does not necessarily predict the presence of alterations at other loci on the same chromosome, i.e. FISH may not detect partial allelic loss. FISH may not detect allelic losses if there is loss of one allele and replication on the other allele.

Comment: Allelic loss on chromosome 1p has been shown to correlate with chemoresponsiveness and long progression-free survival in some gliomas. This correlation is stronger when there is concomitant allelic loss on 19q. An association of chemoresponsiveness and/or long progression-free survival with allelic loss on 19q in the absence of loss on 1p has not been established. In patients with 1p/19q loss, aneusomy for chromosome 1 and 19 may be associated with earlier recurrence. References: Cairncross et al J Natl Cancer Inst 90:1473-1479, 1998; Smith et al, J Clin Oncol 18:636-645, 2000; Ino et al, J Neurosurg 92:983-990, 2000; Schmidt et al, J Neuropathol Exp Neurol 61:321-328, 2002; Snuderl et al, ClinCancer Res 15:6430-7, 2009.

Method: The integrity of the short arm of chromosome 1 (1p) and long arm of chromosome 19 (19q) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using locus-specific probes target (1p36, 19q13) and reference probes (1q25, 19p13)

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

The analysis was performed on areas of glial neoplasm and only atypical nuclei with two or more reference probe signals were counted. Reported quantitative data represents an average of 40 nuclei. Loss is defined as a ratio of less than or equal to 0.7. Aneusomy is defined as a mean of greater than or equal to 3.0 for the reference probe signals (1q25, 19p13).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the [redacted] The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

Procedure: FISH for EGFR

Status: Signed Out

Text: ***** EGFR FISH RESULTS *****

RESULTS: EGFR NOT AMPLIFIED

SPECIMEN SUBMITTED: Paraffin block A3

Interpretation : Amplification of the Epidermal Growth Factor Receptor gene (EGFR) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using EGFR (7p12) and chromosome 7 paracentromeric (7p11.1-q11.1) (CEP7) locus specific directly labeled probes

The following FISH results were obtained:

EGFR 2.3

CEP7 2.4

EGFR/CEP7 ratio 1.0

Aneusomy of chromosome 7 is not identified.

Comment: There is some indication in the literature that EGFR amplification may correlate with survival and prognosis in some patients with gliomas (Smith JS, et al., J Natl Canc Inst 93:1246-1256, 2001; Ino et al., J Neurosurgery 92:983-990 2000).

ANALYTE SPECIFIC REAGENT (ASR) DISCLAIMER

This test was developed and its performance characteristics determined by the [redacted] The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

Intraoperative Diagnosis:

A. Low grade glioma

Clinical Diagnosis:

H/O LEFT TEMPORAL TUMOR

Gross Description:

A. Received fresh for frozen section labeled "left temporal tumor mass" is an irregular shaped segment of tan soft tissue measuring 2.5 x 1.5 x 1 cm. The specimen is sectioned to reveal an unremarkable cut surface. No distinct mass lesion is identified. The specimen is totally submitted as follows: A1 frozen section, keep frozen, A2-A4 remainder of specimen submitted in formalin.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file 39ffad94-f256-4dfa-a4ba-c251d481b960 (TCGA-FG-A60L.E6DA1846-7274-44A3-99DE-65EE1FC91D6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).